Somatic mutation profile of tumor specimen BA2844D (aliquot aq-BA2844D) from BEATAML1.0 case 2275, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.2 years (22,341 days).
Specimen BA2844D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8281018b-36a4-4e86-bd08-2b31e49dff6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2108D (Solid Tissue Normal), aliquot aq-BA2108D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fa4622a-f43d-4afc-8386-34b5c49254b5

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Nonsense Mutation 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITPRIPL1 | c.989G>A p.W330* (on ENST00000439118 / NM_001008949.3; = p.W338* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV63152574; called by muse, varscan2
- PDZRN4 | c.1058C>A p.T353N (on ENST00000402685 / NM_001164595.2; = p.T95N on NM_013377.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1194240391, COSV100115451; called by muse, varscan2
- GRID2 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- PYM1 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC18A3 | c.850C>A p.R284S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, varscan2
- ZNF83 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); called by muse, varscan2
- CCDC88C | c.3939G>T p.S1313= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, varscan2
- KCNH5 | c.2214C>T p.S738= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV59781091; called by muse, varscan2
- NOP9 | c.303C>A p.S101= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, varscan2
- PEAK3 | c.960G>T p.T320= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- FAM86C2P | n.913G>A | RNA (SNP) | VAF 16/82 reads (20%) | catalogued as rs765260638; called by muse, varscan2
- MED13L | c.4115-45G>T | Intron (SNP) | VAF 4/57 reads (7%) | catalogued as rs993745911; called by muse, mutect2
